Surgical pathology report (de-identified scan), TCGA case TCGA-76-4927, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4927-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Left frontal brain lesion: glioblastoma multiforme, grade IV of IV (WHO scale), see microscopic description
2. SPECIMEN NOT RECEIVED:
3. SPECIMEN NOT RECEIVED:
4. SPECIMEN NOT RECEIVED:
5. Left frontal lobe brain lesion: glioblastoma multiforme, grade IV of IV (WHO scale), see microscopic description
6. Left frontal lobe lesion: glioblastoma multiforme, grade IV of IV (WHO scale), see microscopic description

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Microscopic Description:

The tumor consists of a moderately pleomorphic proliferation of infiltrative astrocytic cells. There is abundant endothelial proliferation and extensive necrosis. There is a brisk mitotic rate. The findings are diagnostic of a glioblastoma multiforme, grade IV of IV (WHO scale).

[page 2 of 3]
Frozen Section Diagnosis:

1. Atypical and reactive glial cells, necrosis and abnormal blood vessels. Findings are suspicious for glial neoplasm. More tissue requested if clinically indicated.
2. High-grade malignant glioma.

Clinical History and Diagnosis:
Left frontal lobe brain lesion

Source of Specimen:

- 1: Left frontal brain lesion
- 2: SPECIMEN NOT RECEIVED
- 3: SPECIMEN NOT RECEIVED
- 4: SPECIMEN NOT RECEIVED
- 5: Left frontal lobe brain lesion
- 6: Left frontal lobe lesion

Gross Description:

1. Left frontal brain lesion: Received fresh are two fragments of red-tan soft tissue measuring 0.8 x 0.4 x 0.2 centimeters each. Approximately 60% of the specimen is submitted for frozen section in one cassette. Touch preparation slides are created. The remainder of the specimen is entirely submitted in one cassette for permanent section.

2. SPECIMEN NOT RECEIVED:

3. SPECIMEN NOT RECEIVED:

4. SPECIMEN NOT RECEIVED:

5. Left frontal lobe brain lesion: Received in formalin is a white and red soft tissue measuring 0.7 x 0.6 x 0.2 cm. The specimen is entirely submitted in one cassette.

[page 3 of 3]
6 Left frontal lobe lesion: Received in formalin are multiple fragments of red-tan soft tissue measuring 1.5 x 1.5 to 0.9 cm in aggregate. Touch preparation slides are created. 50% of the specimen is submitted for frozen section. The remainder of the specimen is entirely submitted in one cassette for permanent section.

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file 9f495b7a-d2cb-4ea7-9d43-8ac8d8917f32 (TCGA-76-4927.5F1A707B-6ACD-45B3-8540-0FF1EC834AB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).